Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A9TE, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A9TE-01A (Primary Tumor).

[page 1 of 4]
Referring Physician:

DOB: Age: Gender: M

Room

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. LYMPH NODES, RIGHT PELVIC, REGIONAL RESECTION:
- FOUR LYMPH NODES, NO TUMOR SEEN (0/4).
- B. LYMPH NODES, LEFT PELVIC, REGIONAL RESECTION:
- ONE OF THREE LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA (1/3).
- C. PROSTATE, RADICAL PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON 5+4=9.
- EXTENSIVELY INVOLVES RIGHT AND LEFT LOBES OF PROSTATE.
- EXTRAPROSTATIC EXTENSION IDENTIFIED.
- SEMINAL VESICLE INVASION IDENTIFIED.
- EXTENSIVE PERINEURAL INVASION IDENTIFIED.
- SURGICAL MARGINS POSITIVE, SEE COMMENT.

COMMENT: The tumor involves multiple surgical margins along the left aspect of the prostatectomy specimen to include left posterior, left apex, left lateral and left base. Additionally, the left vas deferens margin is positive for adenocarcinoma.

PATHOLOGIC TUMOR STAGING SYNOPSIS (PROSTATE GLAND):

Type and grade: Prostatic adenocarcinoma, Gleason 5+4=9.

Primary tumor: pT3b.

Regional lymph nodes: pN1.

Distant metastasis: N/A.

Pathologic stage: IV.

Lymphovascular invasion: Not identified.

Margin status: R1, positive.

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 061.9
J4 5/5/14

Prostate Tumor Staging Information

AJCC Cancer Staging Handbook, 7th Ed., and CAP Protocol (revised June 2012).
Previous pathology specimens:

Case #:

Printed:

Page 1

This report continues... (FINAL)

MR No. .

Acct No

Patient Name

Pathology - Page 1/4

Doc# 1

[page 2 of 4]
Patient:

Case #:

Procedure:

Prostate size:

Lymph node sampling:

Histologic type:

Histologic grade/Gleason pattern:

Tumor quantitation:

Extraprostatic extension:

Seminal vesicle invasion:

Margins:

Treatment effect on carcinoma:

Lymph-vascular invasion:

Pathologic staging:

Primary tumor

Regional lymph nodes

Distant metastasis

Pathologic stage

Radical prostatectomy and regional lymph node resections.

45 grams, 2.8 x 3.6 x 3.0 cm.

Right and left pelvic lymph nodes (1 of 7 lymph nodes positive for metastatic adenocarcinoma).

Adenocarcinoma.

Gleason 5+4=9, tertiary pattern 3.

95% of tissue sampled.

Present.

Present.

R1, positive at left posterior, apex, lateral, base and left vas deferens margins.

N/A.

Not identified.

pT3a.

pN1.

N/A.

IV.

Signed by

Source of Specimen:

A. Lymph node; Pelvic lymph nodes right side

B. Lymph node; Pelvic lymph nodes left side

C. Prostatectomy

Clinical History/Operative Dx:

Prostate cancer

Gross Description:

A. Received in formalin is a 11 gram aggregate of tattered, lobular yellow-tan fatty soft tissue measuring 6.5 x 3.0 x 1.0 cm. Examination reveals four lymph nodes that are fatty-yellow, to rubbery pink and tan, ranging from 1.0 x 0.7 x 0.3 cm to 5.0 x 0.7 x 0.4 cm each. The lymph node tissue is entirely submitted for microscopic evaluation.

Cassette summary:

Case #:

Printed:

Page 2

This report continues... (FINAL)

MR No.

athology - Page 2/4

2 Doc# 1

[page 3 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

A1) large node bisected,
A2) smallest node,
A3) single lymph node bisected,
A4-A5) elongated lymph node bisected lengthwise and submitted as four pieces.

B. Received in formalin are multiple yellow-tan to fatty soft tissue weighing in aggregate of 10 grams and measuring 7.8 x 3.5 x 1.5 cm. Examination reveals four lymph nodes ranging from 0.3 cm to 4.0 x 1.1 x 0.5 cm each. Lymph node tissue is entirely submitted for microscopic evaluation.

Cassette summary:

B1) single small lymph node,
B2) single lymph node, grossly suspicious for tumor involvement, bisected,
B3) single lymph node bisected,
B4-B5) elongated lymph node bisected lengthwise, submitted as four pieces

C. Initially received in the fresh state for tumor bank harvest is a radical prostatectomy with attached seminal vesicles and vas deferens pieces weighing an aggregate 45 grams. The prostate is 2.8 cm apex to base, 3.6 cm right to left lateral, and 3.0 cm posterior-anterior. The right vas segment extends out to 2.5 cm and 0.4 cm in diameter and the left vas extends 2.3 x 0.5 cm. The right seminal vesicles are flattened, measuring 2.0 x 1.3 x 1.3 cm and the left seminal vesicles are flattened, measuring 2.5 x 1.5 x 1.0 cm. Sectioning through the bilateral seminal vesicles demonstrates grossly fibrous, rubbery to indurated appearance, with poorly definitive honeycomb architecture. The radial margin of the prostate is now differentially inked as follows:

Right anterior-lateral: Blue,
Left anterior-lateral: Orange,
Posterior: Black.

The prostate is serially sectioned apex to base (slabs 1-7, respectively; slabs 5 and 6 include only the posterior and lateral margins). The cut sections reveal profuse, ill-defined areas of granular, yellow-red and glistening, pink and tan, fleshy changes, bilaterally from the apex towards the base (slabs 1-7).

In addition, multiple circumscribed, light pink and tan nodularities or oriented near the urethra. Representative sections of the likely tumor along with representation of the grossly uninvolved seminal vesicles are submitted for tumor bank studies. Representative sections are submitted.

Cassette summary:

C1) right vas margin, base of seminal vesicles,
C2) left vas margin, base of seminal vesicles,
C3-C4) right and left apex, respectively, slab 1,
C5-C6) right base, slab 7,
C7-C8) left base, slab 7,
C9) right anterior, slab 2,
C10) right anterior, slab 3,
C11) right anterior, slab 4,

Case #:

Printed:

Page 3

This report continues... (FINAL)

MR No. -

Acct No. -

Patient Name -

[page 4 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

- C12) right posterior, slab 2,
- C13) right posterior, slab 3,
- C14) right posterior, slab 4,
- C15) right posterior, including origin of seminal vesicles, slab 6,
- C16) right posterior, slab 7,
- C17) left anterior, slab 2,
- C18) left anterior, slab 3,
- C19) left anterior, slab 4,
- C20) left anterior-lateral, slab 5,
- C21) left posterior, slab 2,
- C22) left posterior, slab 3,
- C23) left posterior, slab 4, site harvested for tumor bank studies,
- C24) left posterior, slab 5, two pieces,
- C25) left posterior, slab, including origin of seminal vesicles, slab 6,
- C26) left posterior, slab 7.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Unless specified otherwise above, the quality of the H & E and any other special stains performed at (AFB. PAS, immunostains, etc) is satisfactory, and any internal or external positive and negative controls react appropriately. Photographs that may be included in this report represent only selected aspects of the pathologic examination, and should not be considered diagnostic by themselves.

Case #:

Printed:

MR No.

Pathology - Page 4/4

Source: NCI Genomic Data Commons file 937774ca-c67a-46cd-9b5d-0261f6e79371 (TCGA-HC-A9TE.BC2B6EED-5BD7-407D-AFAD-47A611F3C62C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).